Somatic mutation profile of tumor specimen TCGA-EX-A1H5-01A (aliquot TCGA-EX-A1H5-01A-31D-A13W-08) from TCGA case TCGA-EX-A1H5, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 58.4 years (21,338 days).
Specimen TCGA-EX-A1H5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cffc52b6-ba5b-4197-8d75-9dc5a148d5eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EX-A1H5-10A (Blood Derived Normal), aliquot TCGA-EX-A1H5-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a56e9b54-ad84-453c-9781-c54036aa29f0

The open-access MAF lists 47 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 12, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 184/228 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PHF6 | c.820C>T p.R274* (on ENST00000332070 / NM_032458.3; = p.R275* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 19/188 reads (10%) | catalogued as rs1556019107, COSV59699330; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 103/290 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.479); catalogued as COSV55746804; called by muse, mutect2, varscan2
- ADGRB1 | c.3517G>A p.D1173N | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as rs755969656, COSV60093813; called by muse, mutect2, varscan2
- ALPK1 | c.2422A>C p.N808H | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.135); catalogued as COSV51583538; called by muse, mutect2, varscan2
- CDH20 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1411551563, COSV53007346; called by muse, mutect2, varscan2
- CLIP3 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs1346025472, COSV62112083; called by muse, mutect2, varscan2
- COL11A2 | c.1297C>T p.R433* (on ENST00000341947 / NM_080680.3; = p.R326* on NM_080679.2) | Nonsense Mutation (SNP) | VAF 42/113 reads (37%) | catalogued as COSV59495092; called by muse, mutect2, varscan2
- DSEL | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV59490420; called by muse, mutect2, varscan2
- DZANK1 | c.1229G>A p.R410H (on ENST00000262547 / NM_001099407.1; = p.R211H on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs750727435, COSV52748522, COSV52749420; called by muse, mutect2, varscan2
- EYS | c.1641_1644del p.S547Rfs*62 (on ENST00000370621 / NM_001292009.1; = p.S547Rfs*58 on NM_198283.1) | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | catalogued as rs752504462; called by mutect2, pindel, varscan2
- GRIK3 | c.2338A>T p.T780S | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.144); catalogued as COSV66137700; called by muse, mutect2, varscan2
- HLA-DMB | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as COSV66870642; called by muse, mutect2, varscan2
- KALRN | c.4553C>T p.T1518M | Missense Mutation (SNP) | VAF 66/121 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs780998165, COSV53758713; called by muse, mutect2, varscan2
- KCNG1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.1); catalogued as COSV65368649, COSV65370663; called by muse, mutect2, varscan2
- KLHDC7B | c.1295C>T p.A432V (on ENST00000395676; = p.A1073V on NM_138433.5) | Missense Mutation (SNP) | VAF 91/109 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67464380; called by muse, mutect2, varscan2
- MBD3L1 | c.500G>C p.R167T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs760213766, COSV59775833; called by muse, mutect2, varscan2
- PLEKHM2 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV65395703; called by muse, mutect2
- PLEKHM3 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs750548446, COSV66816107; called by muse, mutect2, varscan2
- PLXNA3 | c.1979G>A p.R660H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs149034613, COSV63753615; called by muse, mutect2
- POTEF | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs1332080384, COSV62540551; called by muse, varscan2
- PSEN2 | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.741); catalogued as rs757273954, COSV60915458; called by muse, mutect2, varscan2
- RECK | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs142114378; called by muse, mutect2, varscan2
- RGP1 | c.1050G>A p.W350* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV65239141; called by muse, mutect2, varscan2
- SEC61A2 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 63/98 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as COSV53651505; called by muse, mutect2, varscan2
- SLC25A1 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV53205489; called by muse, mutect2, varscan2
- TMEM132E | c.949C>T p.R317W (on ENST00000321639; = p.R407W on NM_001304438.2) | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371393529, COSV58695340; called by muse, mutect2, varscan2
- WDR7 | c.3949A>G p.M1317V | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV54350735; called by muse, mutect2, varscan2
- ZMYM1 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as rs778985156, COSV63250961; called by muse, mutect2, varscan2
- ZNF493 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs768366232, COSV62749585; called by muse, mutect2, varscan2
- DMD | c.7252del p.Q2418Kfs*3 | Frame Shift Del (DEL) | VAF 50/156 reads (32%) | called by mutect2, pindel, varscan2
- GTF3C1 | c.530_532del p.S177del | In Frame Del (DEL) | VAF 9/92 reads (10%) | called by mutect2, pindel
- NBPF15 | c.1829G>A p.R610K | Missense Mutation (SNP) | VAF 233/610 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- RABGAP1 | c.1091_1101+34del p.X364_splice | Splice Site (DEL) | VAF 50/196 reads (26%) | called by mutect2, pindel
- AC005833.1 | c.987C>T p.V329= | Silent (SNP) | VAF 50/100 reads (50%) | catalogued as rs767214354, COSV52895869; called by muse, mutect2, varscan2
- CASZ1 | c.4743G>A p.T1581= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV65457195; called by muse, mutect2
- DDR2 | c.1206T>C p.I402= | Silent (SNP) | VAF 18/280 reads (6%) | catalogued as COSV63370241; called by muse, mutect2
- DISP1 | c.2250C>T p.S750= | Silent (SNP) | VAF 73/208 reads (35%) | catalogued as rs377033862, COSV99449803; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPB41 | c.345G>A p.E115= | Silent (SNP) | VAF 94/270 reads (35%) | catalogued as COSV58044331; called by muse, mutect2, varscan2
- GAB1 | c.1038G>A p.P346= | Silent (SNP) | VAF 40/57 reads (70%) | catalogued as rs751053363, COSV53755463; called by muse, mutect2, varscan2
- LNPEP | c.1011C>T p.V337= | Silent (SNP) | VAF 82/146 reads (56%) | catalogued as rs142457895; called by muse, mutect2, varscan2
- LRRN4CL | c.360C>T p.D120= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs1306150310, COSV54015044; called by muse, mutect2
- MAPK8IP3 | c.1384T>C p.L462= | Silent (SNP) | VAF 46/62 reads (74%) | catalogued as rs1183224084, COSV51718303; called by muse, mutect2, varscan2
- PASD1 | c.1842G>A p.Q614= | Silent (SNP) | VAF 53/156 reads (34%) | catalogued as COSV64854676; called by muse, mutect2, varscan2
- PIK3C2B | c.3504C>T p.D1168= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs368654473; called by muse, mutect2, varscan2
- PSD4 | c.2529C>T p.H843= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV55525561; called by muse, mutect2, varscan2
- CRYM-AS1 | n.397C>T | RNA (SNP) | VAF 186/451 reads (41%) | catalogued as rs768837894; called by muse, mutect2, varscan2
